MMRF case MMRF_1171 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c5221054-2494-4550-861f-090790b498e6

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 36 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 36.4 years (13,280 days); ISS stage: II; Days to last known disease status: 1,588 days (4.3 years); Days to last follow up: 1,588 days (4.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 89 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 155 days; Days to treatment end: 155 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 155 days; Days to treatment end: 155 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 245 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -22 (ECOG 0): M Protein 6.06 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.05 mg/dL; Immunoglobulin G 68.4 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 1.99 µg/mL; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 272 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 32 g/L; Total Protein 11.6 g/dL; Glucose 5.89 mmol/L; C-Reactive Protein 0.304 mg/dL.
- Day 89 (ECOG 0): M Protein 0.69 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.05 mg/dL; Immunoglobulin G 13.8 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 1.48 µg/mL; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.72 ×10⁹/L; Platelets 352 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 7.3 g/dL; Glucose 3.96 mmol/L.
- Day 170 (ECOG 1): M Protein 0.77 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.06 mg/dL; Immunoglobulin G 14.7 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 0.86 g/L; Beta 2 Microglobulin 1.65 µg/mL; Lactate Dehydrogenase 3.25 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.93 ×10⁹/L; Platelets 96 ×10⁹/L; Creatinine 45.1 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.33 mmol/L; Albumin 34 g/L; Total Protein 7.1 g/dL; Glucose 5.01 mmol/L.
- Day 252 (ECOG 1): M Protein 0.59 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.52 mg/dL; Immunoglobulin G 15.9 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 0.56 g/L; Beta 2 Microglobulin 1.82 µg/mL; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.68 ×10⁹/L; Platelets 280 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.48 mmol/L; Albumin 43 g/L; Total Protein 8.4 g/dL; Glucose 5.67 mmol/L.
- Day 370: M Protein 0.48 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.65 mg/dL; Immunoglobulin G 13.7 g/L; Immunoglobulin A 0.76 g/L; Immunoglobulin M 0.56 g/L; Beta 2 Microglobulin 1.37 µg/mL; Lactate Dehydrogenase 2.27 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.07 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 44.3 g/L; Total Protein 6.8 g/dL; Glucose 5.34 mmol/L.
- Day 464 (ECOG 1): M Protein 0.48 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.87 mg/dL; Immunoglobulin G 13.8 g/L; Immunoglobulin A 1.09 g/L; Immunoglobulin M 0.51 g/L; Beta 2 Microglobulin 1.6 µg/mL; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.43 ×10⁹/L; Platelets 244 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 7.8 g/dL; Glucose 6.05 mmol/L.
- Day 565: M Protein 0.64 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.142 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.124 mg/dL; Immunoglobulin G 13.7 g/L; Immunoglobulin A 1.59 g/L; Immunoglobulin M 0.46 g/L; Hemoglobin 8.37 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.51 ×10⁹/L; Platelets 246 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 41.1 g/L; Total Protein 7.3 g/dL; Glucose 5.61 mmol/L.
- Day 751: M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.165 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.161 mg/dL; Immunoglobulin G 15.7 g/L; Immunoglobulin A 2.17 g/L; Immunoglobulin M 0.5 g/L; Hemoglobin 8.62 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 252 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.23 mmol/L; Albumin 45.5 g/L; Total Protein 8.1 g/dL; Glucose 6.11 mmol/L.
- Day 860 (ECOG 0): M Protein 0.62 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.64 mg/dL; Immunoglobulin G 15 g/L; Immunoglobulin A 2.24 g/L; Immunoglobulin M 0.55 g/L; Beta 2 Microglobulin 1.66 µg/mL; Lactate Dehydrogenase 3.28 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 257 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.38 mmol/L; Albumin 44 g/L; Total Protein 8.4 g/dL; Glucose 5.06 mmol/L.
- Day 959 (ECOG 0): M Protein 3.1 g/dL; Immunoglobulin G 14.2 g/L; Immunoglobulin A 2.53 g/L; Immunoglobulin M 0.56 g/L; Hemoglobin 8.62 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 7.8 g/dL; Glucose 5.56 mmol/L.
- Day 1,016 (ECOG 0): M Protein 0.72 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.115 mg/dL; Immunoglobulin G 15.7 g/L; Immunoglobulin A 2.75 g/L; Immunoglobulin M 0.54 g/L; Hemoglobin 9.18 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 267 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 7.9 g/dL; Glucose 6.49 mmol/L.
- Day 1,224 (ECOG 0): M Protein 0.59 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.29 mg/dL; Immunoglobulin G 16.1 g/L; Immunoglobulin A 3.16 g/L; Immunoglobulin M 0.97 g/L; Beta 2 Microglobulin 1.47 µg/mL; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.74 ×10⁹/L; Platelets 242 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 8 g/dL; Glucose 5.28 mmol/L.
- Day 1,262 (ECOG 0): M Protein 0.55 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.174 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.116 mg/dL; Immunoglobulin G 15 g/L; Immunoglobulin A 2.99 g/L; Immunoglobulin M 0.75 g/L; Hemoglobin 9.11 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 268 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 45.4 g/L; Total Protein 8.4 g/dL; Glucose 5.01 mmol/L.
- Day 1,408 (ECOG 0): M Protein 0.67 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.166 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.157 mg/dL; Immunoglobulin G 14.3 g/L; Immunoglobulin A 2.58 g/L; Immunoglobulin M 0.53 g/L; Hemoglobin 8.49 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 7.7 g/dL; Glucose 5.12 mmol/L.
- Day 1,478: Hemoglobin 8.87 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 372 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 8.8 g/dL; Glucose 5.83 mmol/L.
- Day 1,588: M Protein 0.63 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.56 mg/dL; Immunoglobulin G 14.6 g/L; Immunoglobulin A 3.91 g/L; Immunoglobulin M 0.73 g/L; Beta 2 Microglobulin 1.79 µg/mL; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.12 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 7.4 g/dL; Glucose 5.28 mmol/L.

Other clinical attributes
- Day -22: Weight: 86 kg; Height: 164 cm.

Biospecimens (2 samples)
- Sample MMRF_1171_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -22 days.
- Sample MMRF_1171_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -22 days.
